MMRF case MMRF_1986 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/90cb3d92-24d4-4967-bba8-b19fe2de036a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.5 years (25,372 days); ISS stage: II; Days to last known disease status: 1,021 days (2.8 years); Days to last follow up: 1,021 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 13 days; Days to treatment end: 398 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 13 (ECOG 1): M Protein 9.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 137 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Beta 2 Microglobulin 5.24 µg/mL; Hemoglobin 4.34 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 269 µmol/L; Blood Urea Nitrogen 18.2 mmol/L; Calcium 2.13 mmol/L; Albumin 21 g/L; Total Protein 12.9 g/dL; Glucose 8.91 mmol/L.
- Day 112 (ECOG 1): Hemoglobin 7.75 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 7.21 mmol/L.
- Day 195 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.6 mg/dL; Immunoglobulin G 6.88 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.89 mmol/L.
- Day 258 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.1 mg/dL; Immunoglobulin G 5.13 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.
- Day 356 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.3 mg/dL; Immunoglobulin G 5.59 g/L; Immunoglobulin A 2.9 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 8.47 mmol/L.
- Day 482 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 8.74 g/L; Immunoglobulin A 3.38 g/L; Immunoglobulin M 0.753 g/L; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 7.15 mmol/L.
- Day 572 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 6.22 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.351 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 6.99 mmol/L.
- Day 636 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 331 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 713 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 7.72 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 7.8 g/dL; Glucose 6.11 mmol/L.
- Day 832 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.39 mmol/L.
- Day 923 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 1.92 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 6.11 mmol/L.
- Day 1,021 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 8.98 g/L; Immunoglobulin A 2.1 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.7 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 13: Weight: 72 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1986_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 13 days.
- Sample MMRF_1986_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 13 days.
